Surgical pathology report (de-identified scan), TCGA case TCGA-22-5485, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-22-5485-01A (Primary Tumor).

TCGA-22-5485

DIAGNOSIS:

Lung, right upper lobe, wedge excision: Grade 3 (of 4) squamous cell carcinoma (1.8 x 1.7 x 1.4 cm).

Lung, right upper lobe, lobectomy: Grade 3 (of 4) adenocarcinoma, 1.2 cm in diameter. Bronchial resection margin is negative for tumor. Multiple (1) peribronchial and (1) intrapulmonary peribronchial lymph nodes are negative for tumor.

Lymph nodes, superior mediastinal, inferior mediastinal, N1, excision: Multiple superior mediastinal (1 right upper paratracheal, 9 right lower paratracheal, 1 right tracheo-bronchial), inferior mediastinal (1 subcarinal, 1 paraesophageal, 1 right inferior pulmonary ligament), and N1 (2 right interlobar) lymph nodes are negative for tumor.

Source: NCI Genomic Data Commons file 137b95c6-f56b-4592-9489-b86913a0c3fe (TCGA-22-5485.1A1ABB9B-FE80-4A56-A276-94135FCEDF4B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).